Gene-level copy-number profile of tumor specimen TCGA-AA-A00D-01A from TCGA case TCGA-AA-A00D, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 70.3 years (25,689 days).
Specimen TCGA-AA-A00D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.fa63b114-1e68-49f5-88c1-117d50507880.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A00D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e88a7f1b-85f3-4612-ac5b-06b43ee9404f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 658; copy number 1: 7,034; copy number 2: 43,575; copy number 3: 5,442; copy number 4: 872; copy number 5: 2,002; copy number 6: 415; copy number 9: 24; copy number 12: 220; copy number 14: 4; copy number 16: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-A00D-01): tumor purity 0.52, ploidy 2.16, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:7,870,852–7,972,759, 5 genes (within-gene range 0–2): AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6.
- chr18:6,374,361–7,461,135, 24 genes: MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1.
- chr18:7,741,310–7,815,730, 2 genes: AP000897.2, AP000897.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,135 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:40,900,016–145,066,685, 1,616 genes, copy number 5–16 (broad region; genes not listed).
- chr13:20,403,666–28,778,937, 197 genes, copy number 5 (broad region; genes not listed).
- chr13:55,128,285–55,583,524, 3 genes, copy number 5: AL139038.1, MIR5007, AL354821.1.
- chr13:94,025,470–114,337,626, 319 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,276. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
